Gene-level copy-number profile of specimen HCM-SANG-1323-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-1323-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-1323-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a1910077-184a-4464-9262-f1ddc4e2a1bb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1323-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/d6c51d77-72ea-4570-9cb9-7cdc7b82b71c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,165; copy number 2: 28,560; copy number 3: 17,312; copy number 4: 10,253; copy number 5: 898; copy number 6: 192; copy number 7: 199; copy number 8: 93; copy number 9: 107; copy number 10: 46; copy number 12: 2; copy number 22: 13; copy number 27: 56; copy number 28: 2; copy number 32: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,585 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:32,600,172–32,725,237, 5 genes, copy number 5 (within-gene range 4–5): ZBTB8OS, Y_RNA, RBBP4, SYNC, AC114489.1.
- chr3:57,548,838–59,754,808, 37 genes, copy number 5–6 (within-gene range 3–6): RNU6-483P, PDE12, ARF4, ARF4-AS1, RNU6ATAC26P, DENND6A, DENND6A-AS1, DENND6A-DT, SLMAP, PDHA1P1, PPIAP16, FLNB, FLNB-AS1, DNASE1L3, ABHD6, HTD2, RPP14, AC098479.1, PXK, AC135507.2, PDHB, AC135507.1, AC116036.2, KCTD6, ACOX2, AC116036.1, FAM107A, AC119424.1, FAM3D-AS1, FAM3D, CFAP20DC, CFAP20DC-AS1, AC126121.3, AC138057.1, AC126121.2, AC126121.1, Metazoa_SRP.
- chr3:90,202,316–90,261,708, 2 genes, copy number 5: PROS2P, HSPE1P19.
- chr3:195,699,401–198,123,232, 96 genes, copy number 7 (broad region; genes not listed).
- chr5:40,512,333–45,895,970, 83 genes, copy number 5–27 (broad region; genes not listed).
- chr7:17,679,549–17,680,659, 1 gene, copy number 5: AC006482.1.
- chr7:71,132,144–71,713,600, 3 genes, copy number 5 (within-gene range 4–6): GALNT17, MIR3914-1, MIR3914-2.
- chr7:71,779,491–73,624,543, 51 genes, copy number 6: CALN1, RNA5SP232, AC005011.1, ABCF2P2, TYW1B, MIR4650-2, AC211469.2, AC211469.1, RN7SL377P, SBDSP1, RN7SL625P, SPDYE7P, POM121, AC211476.2, NSUN5P2, TRIM74, STAG3L3, AC211476.1, Y_RNA, PMS2P7, Y_RNA, SPDYE8, PMS2P8, Y_RNA, AC211476.5, AC211476.3, SPDYE11, AC211476.4, Y_RNA, SPDYE9, PMS2P6, Y_RNA, SPDYE10P, GTF2IP4, PHBP5, NCF1B, GTF2IRD2P1, POM121B, NSUN5, TRIM50, AC211485.1, FKBP6, RNU6-1080P, Y_RNA, FZD9, BAZ1B, RNU6-1198P, BCL7B, TBL2, MLXIPL, AC005089.1.
- chr8:10,474,565–10,547,585, 6 genes, copy number 5 (within-gene range 4–5): LINCR-0001, PRSS52P, RNU6-729P, AC104964.1, PRSS51, AC104964.3.
- chr8:10,606,349–10,859,436, 11 genes, copy number 5: RP1L1, MIR4286, C8orf74, RNA5SP252, SOX7, AC105001.2, AC105001.1, PINX1, MIR1322, AC011008.1, AC011008.2.
- chr8:11,202,965–11,203,671, 1 gene, copy number 5: AF131215.7.
- chr8:11,421,476–11,839,304, 10 genes, copy number 5: FAM167A, BLK, AC022239.1, LINC00208, GATA4, C8orf49, NEIL2, SUB1P1, FDFT1, AC069185.1.
- chr8:40,298,697–41,309,473, 10 genes, copy number 5 (within-gene range 2–5): SIRLNT, AC105999.1, AC010857.1, ZMAT4, AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1.
- chr9:134,132,242–138,124,624, 173 genes, copy number 6–12 (broad region; genes not listed).
- chr10:274,190–36,626,138, 587 genes, copy number 5 (broad region; genes not listed).
- chr12:65,017,468–67,753,817, 51 genes, copy number 7–32: AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB, GRIP1, OSBPL9P5, OSBPL9P4, AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1.
- chr13:40,931,924–44,030,461, 59 genes, copy number 5: ELF1, RGS17P1, WBP4, MIR3168, RN7SL597P, KBTBD6, AL354696.2, CALM2P3, KBTBD7, MORF4L1P4, MTRF1, AL354696.1, RAC1P3, NAA16, RNU6-57P, TUBBP2, OR7E36P, OR7E155P, OR7E37P, RGCC, AL354833.1, VWA8, MIR5006, RN7SL515P, RNU6-74P, KARS1P1, VWA8-AS1, RPS28P8, DGKH, AL157932.1, MAPK6P3, CHCHD2P11, FHP1, AKAP11, LINC02341, FABP3P2, TNFSF11, FAM216B, LINC01050, LINC00428, EPSTI1, ZDHHC4P1, DNAJC15, LINC00400, AL138709.1, ENOX1, RPL36P19, ENOX1-AS2, ENOX1-AS1, AL161714.1, AL162713.2, AL162713.1, CCDC122, AL512506.1, LACC1, AL512506.3, AL512506.2, NRAD1, DGKZP1.
- chr14:37,171,888–53,883,740, 232 genes, copy number 5–10 (within-gene range 2–10) (broad region; genes not listed).
- chr15:85,180,200–85,234,795, 1 gene, copy number 9 (within-gene range 4–9): AC044860.1.
- chr15:85,210,053–85,210,299, 1 gene, copy number 9 (within-gene range 4–9): RN7SL428P.
- chr17:27,456,470–27,626,438, 1 gene, copy number 5 (within-gene range 3–5): KSR1.
- chr17:27,526,386–29,551,903, 126 genes, copy number 5 (broad region; genes not listed).
- chr19:15,141,105–15,836,328, 38 genes, copy number 6–10: OR10B1P, RNU6-782P, NOTCH3, MIR6795, EPHX3, BRD4, AC005776.1, AC005776.2, AKAP8, AC005785.1, AKAP8L, AC005785.2, AC006128.1, WIZ, MIR1470, RASAL3, PGLYRP2, CYP4F22, AC011492.1, CYP4F23P, AD000091.1, RPL23AP2, AC093072.1, CYP4F8, CYP4F3, CYP4F10P, CYP4F12, OR10H2, OR10H3, CYP4F24P, AC004597.1, OR10H5, OR10H1, ZNF861P, AC004510.2, LINC01764, UCA1, AC004510.1.

Autosomal genes at a single copy (total copy number 1): 1,165. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
